TCGA case TCGA-08-0354 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: UCSF. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a23511df-ed31-4f3f-9fe5-87a3621c0de9

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 52 years; Vital status: Dead; Days to death: 546 days (1.5 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 52.6 years (19,199 days); Year of diagnosis: 2003; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Poly ICLC; Treatment intent type: Adjuvant; Days to treatment start: 28 days; Days to treatment end: 253 days; Number of cycles: 8; Treatment dose: 1 mL.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 35 days; Days to treatment end: 97 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Erlotinib Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 261 days; Days to treatment end: 320 days; Treatment dose: 450 mg/day.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 261 days; Days to treatment end: 320 days; Number of cycles: 2; Treatment dose: 200 mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carmustine; Initial disease status: Progressive Disease; Days to treatment start: 345 days; Days to treatment end: 390 days (1.1 years); Number of cycles: 2; Treatment dose: 380 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Isotretinoin; Initial disease status: Progressive Disease; Days to treatment start: 345 days; Days to treatment end: 393 days (1.1 years); Number of cycles: 1; Treatment dose: 180 mg; Route of administration: Intravenous.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 53.3 years (19,452 days); Days to diagnosis: 253 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (4 entries)
- Day 253 (post initial treatment): Progression or recurrence: Yes; Days to progression: 253 days.
- Days to follow up: 458 days (1.3 years); Disease response: With Tumor.
- Days to follow up: 546 days (1.5 years); Disease response: With Tumor.
- Karnofsky performance status: 60; Timepoint: Post Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-08-0354-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.8; Shortest dimension: 0.6.
  Slide TCGA-08-0354-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 5.
  Slide TCGA-08-0354-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 15.
- Sample TCGA-08-0354-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-08-0354-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Performance status timing: Post-Adjuvant Therapy.
- Drug treatment 1: Pharmaceutical therapy drug name: Temador.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Pharmaceutical therapy drug name: Tarceva.
- Drug treatment 3: Pharmaceutical therapy drug name: Bcnu.
- Drug treatment 3, Route of administrations: Route of administration: IV.
- Drug treatment 4: Pharmaceutical therapy drug name: Poly LCLC.
- Drug treatment 4, Route of administrations: Route of administration: Other (specify below).
- Drug treatment 5: Pharmaceutical therapy drug name: cis retinoic acid.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 546 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 546 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 253 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-08-0354-01): tumor purity 0.76, ploidy 2, whole-genome doublings 0 (call status: legacy_call).
